Somatic mutation profile of tumor specimen TCGA-AX-A1C8-01A (aliquot TCGA-AX-A1C8-01A-11D-A135-09) from TCGA case TCGA-AX-A1C8, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 77.9 years (28,452 days).
Specimen TCGA-AX-A1C8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 977998d9-27e9-4e65-b3e7-25b56b769ae9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A1C8-10A (Blood Derived Normal), aliquot TCGA-AX-A1C8-10A-01D-A135-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/485b08ae-1766-4973-a290-db8c459b2c12

The open-access MAF lists 80 somatic variants for this specimen: 64 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 14, Nonsense Mutation 2, Frame Shift Del 2, Splice Site 1, Intron 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1268G>T p.G423V (on ENST00000281708 / NM_001349798.2; = p.G343V on NM_018315.5) | Missense Mutation (SNP) | VAF 25/66 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1157879635, COSV55892390, COSV99657129; called by muse, mutect2, varscan2
- PPP2R1A | c.536C>G p.P179R | Missense Mutation (SNP) | VAF 7/12 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs786205228, CM153573, COSV59042232, COSV59042841; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.1382C>G p.A461G | Missense Mutation (SNP) | VAF 27/72 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs397509344, COSV61005273; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.382_390del p.P128_L130del | In Frame Del (DEL) | VAF 9/15 reads (60%) | hotspot (GDC flag); called by mutect2, varscan2
- ABL2 | c.2813C>A p.T938N (on ENST00000502732 / NM_007314.4; = p.T923N on NM_005158.5) | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV61020745; called by muse, mutect2, varscan2
- ABR | c.1712A>G p.E571G (on ENST00000302538 / NM_021962.5; = p.E534G on NM_001092.5) | Missense Mutation (SNP) | VAF 75/107 reads (70%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.742); catalogued as COSV52152175; called by muse, mutect2, varscan2
- BICC1 | c.2572A>G p.I858V | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.891); catalogued as COSV54067198; called by muse, mutect2, varscan2
- C1RL | c.1009A>G p.S337G | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV56926828; called by muse, mutect2, varscan2
- CABIN1 | c.6410T>G p.I2137S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV54089693; called by muse, mutect2
- CACNA1S | c.3609+1G>A p.X1203_splice | Splice Site (SNP) | VAF 9/66 reads (14%) | catalogued as rs754831666, COSV62937012; called by muse, mutect2, varscan2
- CDH19 | c.30G>A p.M10I | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs1489049534, COSV50978750; called by muse, mutect2, varscan2
- CFAP161 | c.59A>G p.Y20C | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.971); catalogued as COSV54430573; called by muse, mutect2, varscan2
- CFHR4 | c.1034T>C p.F345S (on ENST00000367416 / NM_001201551.2; = p.F99S on NM_006684.5) | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.943); catalogued as COSV52236023; called by muse, mutect2, varscan2
- COL22A1 | c.32G>A p.G11D | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.009); catalogued as COSV57362265; called by muse, mutect2, varscan2
- DHX30 | c.2574C>G p.I858M (on ENST00000445061 / NM_138615.3; = p.I819M on NM_014966.3) | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.567); catalogued as COSV53143001; called by muse, mutect2, varscan2
- DNAJC13 | c.6478G>A p.V2160I | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.415); catalogued as COSV53458804, COSV99038227; called by muse, mutect2, varscan2
- EHD2 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.059); catalogued as COSV54411133; called by muse, mutect2, varscan2
- EPO | c.529C>T p.R177W | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53161012; called by muse, mutect2, varscan2
- HECW1 | c.268A>G p.I90V | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.952); catalogued as COSV67837706; called by muse, mutect2, varscan2
- ITGAV | c.574G>C p.D192H | Missense Mutation (SNP) | VAF 6/148 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV53719327, COSV99655281; called by muse, mutect2
- ITPR2 | c.5746G>A p.A1916T | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs1156767315, COSV67276622; called by muse, mutect2, varscan2
- KAT5 | c.631C>T p.R211C | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV57730591; called by muse, mutect2
- KCNA10 | c.1066C>T p.R356C | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768535829, COSV63904462; called by muse, mutect2, varscan2
- KIF4B | c.1520C>A p.S507Y | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as COSV70529464, COSV70531719; called by muse, mutect2
- LRP12 | c.446G>C p.R149T | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.321); catalogued as COSV52634928; called by muse, mutect2, varscan2
- LYST | c.346A>G p.R116G | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.046); catalogued as COSV67714575; called by muse, mutect2
- MED13L | c.3374A>T p.D1125V | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56130897; called by muse, mutect2, varscan2
- MUC16 | c.1553C>T p.S518L | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.35); catalogued as COSV67496111; called by muse, mutect2, varscan2
- MYEF2 | c.1033A>G p.I345V | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.902); catalogued as rs1257673475, COSV51054330; called by muse, mutect2, varscan2
- MYO18B | c.6848C>T p.T2283M | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374097014, COSV59131208; called by muse, mutect2, varscan2
- MYOM2 | c.3143G>A p.R1048Q | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as rs746759229, COSV50706990; called by muse, mutect2, varscan2
- OR51M1 | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.978); catalogued as COSV60785562; called by muse, mutect2, varscan2
- PHF3 | c.6086G>A p.R2029K | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.918); catalogued as rs1024307044, COSV50343899; called by muse, mutect2
- PIWIL4 | c.2044C>G p.H682D | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.39); PolyPhen benign (0.158); catalogued as COSV54412746; called by muse, mutect2, varscan2
- PLXNB2 | c.2480A>G p.N827S | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63784623; called by muse, mutect2, varscan2
- PSMG1 | c.148C>T p.L50F | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV59001460; called by muse, mutect2, varscan2
- PSTPIP2 | c.926G>C p.G309A | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.608); catalogued as COSV68444212; called by muse, mutect2
- PTPRC | c.349A>T p.T117S | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.057); catalogued as COSV61420918; called by muse, mutect2, varscan2
- RGS12 | c.2761G>A p.D921N | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.06); catalogued as rs1185093753, COSV58757331; called by muse, varscan2
- RHPN2 | c.1946G>C p.R649T | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.859); catalogued as COSV54285162; called by muse, mutect2, varscan2
- SCGB1D1 | c.223G>T p.V75L | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs774745314, COSV60378082; called by muse, mutect2, varscan2
- SHC3 | c.1655C>T p.T552M | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as rs764795129, COSV65438054; called by muse, mutect2
- SMG1 | c.8282C>A p.S2761Y | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.446); catalogued as COSV67174957; called by muse, mutect2, varscan2
- SQLE | c.301G>T p.G101* | Nonsense Mutation (SNP) | VAF 7/61 reads (11%) | catalogued as COSV56282788; called by muse, mutect2, varscan2
- SUPT6H | c.964A>T p.R322W | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV58931731; called by muse, mutect2, varscan2
- SYT4 | c.1219G>C p.E407Q | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs1399249030, COSV54904441; called by muse, mutect2
- TBC1D32 | c.2974G>C p.E992Q | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0.074); catalogued as COSV51554655; called by muse, mutect2, varscan2
- TBC1D7 | c.310C>T p.Q104* | Nonsense Mutation (SNP) | VAF 3/28 reads (11%) | catalogued as COSV58245105; called by muse, mutect2
- THRAP3 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1295105395, COSV63566669; called by muse, mutect2, varscan2
- TMEM132B | c.1099G>C p.G367R | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.495); catalogued as COSV54771461; called by muse, mutect2, varscan2
- TOPBP1 | c.2269A>G p.N757D | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1345603794, COSV53442189; called by muse, mutect2, varscan2
- TSHZ3 | c.1099G>A p.G367S | Missense Mutation (SNP) | VAF 44/262 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as rs777524623, COSV53668881, COSV99552976; called by muse, mutect2, varscan2
- TSPOAP1 | c.958G>A p.D320N | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.132); catalogued as COSV52118504; called by muse, mutect2, varscan2
- TSPOAP1 | c.532G>C p.E178Q | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52118529; called by muse, mutect2, varscan2
- UGT2B11 | c.77T>C p.V26A | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV71424460; called by muse, mutect2
- ULK2 | c.1009G>T p.D337Y | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV64448731, COSV64448841; called by muse, mutect2, varscan2
- UQCR10 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.297); catalogued as rs536988546, COSV57459035; called by mutect2, varscan2
- USP24 | c.4943C>T p.S1648L | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as COSV53779282; called by muse, mutect2
- USP9X | c.5263G>A p.E1755K | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV61075537; called by muse, mutect2, varscan2
- WDR3 | c.2385C>G p.I795M | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.051); catalogued as COSV60469110; called by muse, mutect2, varscan2
- XPA | c.484C>G p.L162V | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.277); catalogued as COSV64305784; called by muse, mutect2, varscan2
- ZNF451 | c.2786G>A p.C929Y (on ENST00000370706 / NM_001031623.3; = p.C881Y on NM_015555.2) | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs764565295, COSV62600185; called by muse, mutect2, varscan2
- ABL1 | c.985_1003del p.E329* | Frame Shift Del (DEL) | VAF 3/31 reads (10%) | called by mutect2, pindel
- GRB7 | c.1048_1049del p.Q350Vfs*20 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | called by pindel, varscan2
- ABCB6 | c.1179C>T p.P393= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as rs1292459044, COSV54701134; called by muse, mutect2, varscan2
- AHNAK2 | c.17256G>C p.G5752= | Silent (SNP) | VAF 3/31 reads (10%) | catalogued as COSV60931852; called by muse, mutect2
- ALPK1 | c.2760C>T p.C920= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV51592345; called by muse, mutect2, varscan2
- HIF1A | c.525A>G p.L175= | Silent (SNP) | VAF 25/55 reads (45%) | catalogued as COSV60191910; called by muse, mutect2, varscan2
- KIAA0319 | c.2613A>G p.V871= | Silent (SNP) | VAF 4/49 reads (8%) | catalogued as COSV65502102; called by muse, mutect2
- KMT2E | c.3420T>C p.N1140= | Silent (SNP) | VAF 3/31 reads (10%) | catalogued as COSV57580185; called by muse, mutect2
- MPDZ | c.3606G>A p.L1202= | Silent (SNP) | VAF 25/40 reads (63%) | catalogued as COSV59924988; called by muse, mutect2, varscan2
- MTMR1 | c.1971C>T p.S657= | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as rs1368472543, COSV60937221; called by muse, mutect2
- POU4F3 | c.186G>A p.A62= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV57944103; called by muse, mutect2, varscan2
- PRMT7 | c.1545C>T p.A515= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as COSV59835958; called by muse, mutect2, varscan2
- PYGB | c.2241C>T p.S747= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as COSV53823091; called by muse, mutect2, varscan2
- RNASE3 | c.46T>C p.L16= | Silent (SNP) | VAF 3/44 reads (7%) | catalogued as COSV58960062; called by muse, mutect2
- SYNE2 | c.8442A>G p.Q2814= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as rs1362042654, COSV59971468; called by muse, mutect2, varscan2
- WNT7A | c.123C>A p.I41= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as COSV53202486; called by muse, mutect2, varscan2
- DST | c.4297-4165T>C | Intron (SNP) | VAF 21/57 reads (37%) | catalogued as COSV55041572; called by muse, mutect2, varscan2
- TLX1NB | n.1519A>G | RNA (SNP) | VAF 7/25 reads (28%) | called by muse, mutect2, varscan2
